Surgical pathology report (de-identified scan), TCGA case TCGA-29-1694, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1694-01A (Primary Tumor).

[page 1 of 2]
CLINICAL HISTORY:

Pelvic mass.

TCGA-29-1694

GROSS EXAMINATION:

A. "Omentum", received fresh and placed in formalin. A 15.0 x 7.5 x 2.5 cm aggregate of tan-brown fibroadipose tissue is received. Throughout the specimen, there are multiple foci of circumscribed, firm, white-tan nodules from 0.3 x 0.3 cm to 4.2 x 3.5 cm. Representative sections are submitted in block A1.

B. "Right tube and ovary", received fresh and placed in formalin. A 58 gram, 8.0 x 6.5 x 2.0 cm specimen is received. There is a 5.5 x 0.6 cm portion of fallopian tube which has a smooth, red-tan, cut surface with a paratubal cyst from 0.1 x 0.1 cm to 0.3 x 0.3 cm. Sectioning reveals a pin point lumen. Adjacent to the tube, there is a 9.0 x 5.5 cm diffusely disrupted friable, tan-red mass with a 0.3 cm rim of tan, smooth, normal ovary present. Representative sections of the broken tube is submitted in block B1, and sections of mass and mass adjacent to the normal ovarian tissue is submitted in block B2.

C. "Left tube and ovary", received fresh and placed in formalin. A 32.7 gram, 5.0 x 4.5 x 3.0 cm specimen is received. The specimen consists largely of a friable, tan-red mass partially containing an area of red-tan, focally hemorrhagic serosa. Sectioning reveals a 0.4 cm rim of smooth, white-tan, normal tissue. Representative sections are submitted in blocks C1-C2.

D. "Uterus, cervix", received fresh and placed in formalin. A 120 gram, 8.5 x 8.5 x 5.0 cm uterus is received. The serosa is markedly and diffusely disrupted, covered with a friable, tan-red, focally hemorrhagic mass. The remainder of the serosa is red-tan, smooth, and glistening. The ectocervix is 3.5 x 2.7 cm, and the pink-tan, smooth and glistening. The os is 1.0 cm in diameter and leads into a 2.6 x 0.8 cm tan, trabeculated endocervical canal. The endometrial cavity is 3.2 x 2.0 cm and contains a lush, tan, and 0.3 cm thick endometrium. The myometrium is smooth, pink-tan, focally trabeculated and 2.2 cm thick. Sections are submitted in blocks B1-B6.

BLOCK SUMMARY:

- D1- anterior cervix.
- D2- posterior cervix.
- D3- anterior endomyometrium.
- D4- posterior endomyometrium (endometrial half).
- D5- posterior endomyometrium (serosal half).
- D6- representative serosa.

E. "Pelvic peritoneal", received fresh and placed in formalin. A 7.5 x 6.0 x 2.2 cm aggregate of firm, tan-yellow, focally hemorrhagic tissue is received. Representative sections are submitted in block E1.

F. "Appendix", received fresh and placed in formalin. A 3.5 x 0.5 x 0.5 cm vermiform appendix with a 2.0 x 1.4 cm aggregate of attached yellow-tan fat is received. The serosa is tan-brown, focally hemorrhagic and disrupted and friable at the tip. The surgical end is marked with blue ink, and the specimen is serially sectioned to reveal a 0.2 cm thick wall and a pin point lumen. Representative sections are submitted in block F1. Also received is a 2.5 x 1.5 x 0.8 cm fragment of tan-yellow, focally hemorrhagic, friable tissue. The specimen is serially sectioned and submitted entirely in blocks F3.

[page 2 of 2]
K. [REDACTED]

MICROSCOPIC EXAMINATION:
Microscopic examination is performed.

DIAGNOSIS:

A. "OMENTUM" (EXCISION):

OMENTUM WITH METASTATIC ADENOCARCINOMA.

B. "RIGHT TUBE AND OVARY" (OOPHORECTOMY):

OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA.
NORMAL FALLOPIAN TUBE.

TCGA-29-1694

C. "LEFT TUBE AND OVARY" (OOPHORECTOMY):

OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA.
FALLOPIAN TUBE LUMEN IS NORMAL. CARCINOMA ADJACENT TO THE TUBE.

D. "UTERUS, CERVIX" (TOTAL HYSTERECTOMY):

UTERUS, 120.0 GRAMS
ENDOMETRIUM: SECRETORY.
MYOMETRIUM: NO PATHOLOGIC DIAGNOSIS.
CERVIX: NO PATHOLOGIC DIAGNOSIS.
Serosa: Serosal implants of adenocarcinoma.

E. "PELVIC PERITONEAL" (EXCISION):

FIBROVASCULAR TISSUE WITH METASTATIC ADENOCARCINOMA.

F. "APPENDIX" (APPENDECTOMY):

APPENDIX WITH SEROSAL INVOLVEMENT BY METASTATIC ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 44668875-4b14-42ad-80a1-9e4c3e439397 (TCGA-29-1694.CCFB9F1D-1779-4FAE-A34F-C46A19D4B095.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).